Somatic mutation profile of tumor specimen TCGA-PK-A5H8-01A (aliquot TCGA-PK-A5H8-01A-11D-A29I-10) from TCGA case TCGA-PK-A5H8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 42.1 years (15,373 days).
Specimen TCGA-PK-A5H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2a7954f-aba6-44f3-8beb-23fc86f4645a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PK-A5H8-10A (Blood Derived Normal), aliquot TCGA-PK-A5H8-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/142e4ee8-4569-412c-b44a-ac4093a4170c

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD3 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as rs752394118, COSV53320310; called by muse, mutect2, varscan2
- BNIP5 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV71325646; called by muse, mutect2, varscan2
- CNOT6 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs143354534, COSV56161669; called by muse, mutect2, varscan2
- PDE3A | c.1268A>T p.K423M | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV62981868; called by muse, mutect2, varscan2
- STIL | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs777645890; called by muse, mutect2, varscan2
- TGM6 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486363913; called by muse, mutect2, varscan2
- UNC13C | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.104); catalogued as rs376158849; called by muse, mutect2, varscan2
- ZNF546 | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1299433478; called by muse, mutect2, varscan2
- ANKIB1 | c.2768T>G p.M923R | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB8 | c.413_425del p.L138Pfs*19 | Frame Shift Del (DEL) | VAF 53/118 reads (45%) | called by mutect2, varscan2
- CAPRIN1 | c.879+1G>T p.X293_splice | Splice Site (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- COL25A1 | c.660G>T p.M220I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- FOXO4 | c.1212_1215del p.S405Vfs*14 | Frame Shift Del (DEL) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- INVS | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- NUP188 | c.284_285dup p.Y96Vfs*14 | Frame Shift Ins (INS) | VAF 42/119 reads (35%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1602A>C p.K534N | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- RIPK2 | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFP28 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL21A1 | c.1581C>A p.G527= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, varscan2
- CYLC1 | c.462A>G p.R154= | Silent (SNP) | VAF 72/75 reads (96%) | called by muse, mutect2, varscan2
- FARP2 | c.1422G>C p.T474= | Silent (SNP) | VAF 167/182 reads (92%) | called by muse, mutect2, varscan2
- ITGAV | c.1686G>A p.L562= | Silent (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- THAP5 | c.651A>G p.Q217= (on ENST00000415914 / NM_001130475.3; = p.Q175= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs142576735; called by muse, mutect2, varscan2
